Surgical pathology report (de-identified scan), TCGA case TCGA-DU-6404, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-6404-02A (Recurrent Tumor).

[page 1 of 2]
Anatomic Pathology/Cytology Document State: (version)

Update Date/Time:
Final

Patient Name: MRN:
DOB/Age/Gender: Female Provider:
Location: Responsible Staff:

Service Date/Time:

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: F DOB:

SURGERY DATE:

RECEIVE DATE:

PATIENT PHONE NO.:

PHYSICIAN:

COPY TO:

UPDATED REPORT - SEE ADDENDUM REPORT, ADDENDUM DIAGNOSIS.

PATHOLOGICAL DIAGNOSIS:

A-C. BRAIN, SITE NOT SPECIFIED, EXCISION: OLIGODENDROGLIOMA
WITH ATYPICAL FEATURES.

SEE COMMENT.

ADDENDUM DIAGNOSIS:

MIB-1 PROLIFERATION INDEX: 7%.

1CB-0-3 Recurrence

oligodendroglioma, nos 9450/3

Site: brain, nos 071-9

Operation/Specimen: UPDATED REPORT - Brain.

Clinical History and Pre-Op Dx: year old woman with diagnosis of
oligodendroglioma with anaplastic features in
Currently, recurrence.

hw
2/12/15

GROSS PATHOLOGY:

A. Received fresh, one fragment, 1.2 cm across in largest dimension.
Semi-firm, grayish tan. In total #1-2.

INTRAOPERATIVE CONSULTATION: Brain, smears: Glioma (consistent with
oligodendroglioma).

B. Received fresh, one fragment, 0.8 cm across. Semi-firm, tannishbrown.
In total #3.

C.

SPECIMEN: #1 brain tumor.

FIXATIVE: None.

GENERAL: A 15 x 12 x 3 mm. portion of soft pink-tan tissue.

SECTIONS: 4C - submitted in toto.

D.

SPECIMEN: #2 brain tumor.

FIXATIVE: None.

GENERAL: A 7 x 5 x 2 mm. portion of soft pink-tan tissue.

SECTIONS: 5D - submitted in toto.

E.

SPECIMEN: #3 brain tumor.

FIXATIVE: None.

GENERAL: A 1.7 x 1.5 x 0.8 cm. fragment of soft, pink-tan tissue.

SECTIONS: 6E - submitted in toto.

COMMENT: The neoplasm throughout has an overall morphology of
oligodendroglioma with classical "chicken-wire" microvasculature,
somewhat uniform cellularity, extensive microvascular calcification,
and diffuse infiltration of the gray matter. However, focally the
neoplasm appears fibrillary and somewhat astrocytic. In addition,
mitotic figures are occasionally found, but microvascular cellular

[page 2 of 2]
proliferation is absent, and there are no areas of necrosis. Special stains are being requested to better characterize the neoplasm, and an addendum report will follow.

ADDENDUM REPORT

SPECIAL STAINS: Bielschowsky stain was performed on section from block #4.

The stain demonstrates various densities of axons throughout the tumor.

IMMUNOHISTOCHEMISTRY: Immunoperoxidase methods for GFAP, p53, synaptophysin, and MIB-1 were performed on sections from block #4.

The GFAP depicts reactive astrocytosis throughout the zones of the brain parenchyma infiltrated by the tumor. In these zones there is background synaptophysin immunoreactivity, and rarely a ganglion cell has perikaryal positivity (interpreted as entrapped native neurons). Where there is solid tumor, there is no synaptophysin or GFAP reaction, and with the MIB-1 a proliferation index of 7% is determined. The diagnosis remains as above.

MICROSCOPIC: 6 blocks, 6 slides, 1 special stain, 4 immunoperoxidase stains.

CONSULTANT:

TISSUE COMMITTEE CODE:

ICD9: 191

BILLING CODES:

Source: NCI Genomic Data Commons file e33ab493-3b40-4d84-962a-0362be805da9 (TCGA-DU-6404.C13F0838-3BA3-4C58-BDCC-926F470FFD34.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).